Somatic mutation profile of tumor specimen MP2PRT-PASWRT-TMP1-A (aliquot MP2PRT-PASWRT-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASWRT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,331 days).
Specimen MP2PRT-PASWRT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3009caab-5a17-47f4-ade9-5127e9cf98f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWRT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWRT-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/894bffc1-b251-495d-9228-c403f12998c7

The open-access MAF lists 51 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Intron 2, Nonsense Mutation 2, 3'Flank 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.5912G>C p.R1971T | Missense Mutation (SNP) | VAF 163/353 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58142279; called by muse, mutect2, varscan2
- ADCY5 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 160/313 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs747567385, COSV59206878; called by muse, mutect2, varscan2
- AHNAK | c.15394G>A p.E5132K | Missense Mutation (SNP) | VAF 31/499 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs199553669, COSV57228228; called by muse, mutect2
- C4orf47 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs890740849; called by muse, mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 203/480 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2, varscan2
- CFAP251 | c.3037G>A p.G1013S | Missense Mutation (SNP) | VAF 8/215 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56614419; called by muse, mutect2
- CLTC | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs765478805; called by muse, mutect2
- CRISPLD2 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 146/341 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52282129; called by muse, mutect2, varscan2
- GNB1 | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 21/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101060718, COSV66101380; called by muse, mutect2
- H4C4 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 188/420 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV61590892, COSV61591253, COSV61591576; called by muse, mutect2, varscan2
- IRAK2 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 55/497 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs548063415, COSV56535903; called by muse, mutect2, varscan2
- KCNK17 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs753483930, COSV100949035; called by muse, mutect2
- KRTAP10-1 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 44/1198 reads (4%) | catalogued as COSV100552560; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 185/361 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2L3 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 149/334 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63455446; called by muse, mutect2, varscan2
- SLC26A4 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144691257, CM061989, CM1411212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA5 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 140/330 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs766206272; called by muse, mutect2, varscan2
- SVEP1 | c.7577G>C p.R2526P | Missense Mutation (SNP) | VAF 226/490 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV52835143; called by muse, mutect2, varscan2
- TTN | c.47275G>C p.E15759Q (on ENST00000591111; = p.E8335Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/359 reads (4%) | PolyPhen probably damaging (0.997); catalogued as COSV60280699; called by muse, mutect2
- WDFY3 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as rs757583006, COSV55692194, COSV55697607; called by muse, mutect2, varscan2
- AL031777.2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 271/600 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ANKRD17 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); called by muse, mutect2
- CMTM5 | c.541A>G p.T181A (on ENST00000339180 / NM_001288746.2; = p.T114A on NM_138460.3) | Missense Mutation (SNP) | VAF 204/501 reads (41%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- CTTNBP2 | c.1673C>G p.P558R | Missense Mutation (SNP) | VAF 209/458 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- EYS | c.4156G>C p.D1386H | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.46); called by muse, mutect2
- FAM189A1 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 44/610 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2
- IGHV4-61 | c.349_350insGGG p.C116_A117insG | In Frame Ins (INS) | VAF 82/160 reads (51%) | called by pindel, varscan2
- LTN1 | c.1114C>G p.Q372E | Missense Mutation (SNP) | VAF 157/337 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NCAM2 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OLA1 | c.1171C>G p.Q391E | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMU1 | c.291G>C p.L97F | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SPEN | c.7516G>A p.E2506K | Missense Mutation (SNP) | VAF 240/453 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SVIL | c.1646C>G p.S549* | Nonsense Mutation (SNP) | VAF 173/379 reads (46%) | called by muse, mutect2, varscan2
- TMEM200C | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 67/537 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- VPS13B | c.4684G>A p.E1562K | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABL1 | c.891C>T p.N297= | Silent (SNP) | VAF 90/222 reads (41%) | catalogued as rs756629068; called by muse, mutect2, varscan2
- ACSM6 | c.1062G>A p.E354= | Silent (SNP) | VAF 193/385 reads (50%) | called by muse, mutect2, varscan2
- ADRA2C | c.1068C>T p.F356= | Silent (SNP) | VAF 261/505 reads (52%) | catalogued as rs772863242; called by muse, mutect2, varscan2
- H2BC7 | c.222C>T p.I74= | Silent (SNP) | VAF 185/437 reads (42%) | catalogued as rs763619494, COSV61911556; called by muse, mutect2, varscan2
- LHX5 | c.324C>T p.I108= | Silent (SNP) | VAF 189/411 reads (46%) | catalogued as rs1266819930, COSV55664488; called by muse, mutect2, varscan2
- LRFN3 | c.1206C>T p.D402= | Silent (SNP) | VAF 56/658 reads (9%) | catalogued as rs969220180; called by muse, mutect2
- LYST | c.9357C>T p.L3119= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as COSV67705786; called by muse, mutect2, varscan2
- MROH9 | c.591C>T p.L197= | Silent (SNP) | VAF 142/303 reads (47%) | called by muse, mutect2, varscan2
- MUC5B | c.2529G>A p.S843= | Silent (SNP) | VAF 198/490 reads (40%) | catalogued as rs768009234; called by muse, mutect2, varscan2
- MYH4 | c.2193G>A p.A731= | Silent (SNP) | VAF 96/219 reads (44%) | catalogued as rs574421981; called by muse, mutect2, varscan2
- RPTN | c.885C>T p.Y295= | Silent (SNP) | VAF 241/527 reads (46%) | catalogued as rs200576288, COSV60168525; called by muse, mutect2, varscan2
- USP26 | c.666G>A p.L222= | Silent (SNP) | VAF 36/296 reads (12%) | called by muse, mutect2, varscan2
- AC092070.2 | n.1611G>A | RNA (SNP) | VAF 74/156 reads (47%) | called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins CCTCTCCA | 3'Flank (INS) | VAF 16/130 reads (12%) | called by mutect2, pindel
- TOX3 | c.87+27172C>T | Intron (SNP) | VAF 38/380 reads (10%) | catalogued as rs917346117, COSV54863808; called by muse, mutect2
- UBXN8 | c.88+92C>T | Intron (SNP) | VAF 18/542 reads (3%) | called by muse, mutect2
